Somatic mutation profile of tumor specimen C3L-04212-05 (aliquot CPT0270630006) from CPTAC case C3L-04212, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.5 years (27,946 days).
Specimen C3L-04212-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96be926d-d27e-408d-a07a-a635724b55aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04212-31 (Blood Derived Normal), aliquot CPT0270750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55836645-acf6-44fb-8b30-30d68f122b47

The open-access MAF lists 7,258 somatic variants for this specimen: 4,661 protein-altering or splice-affecting, 2,307 silent, 290 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,289, Silent 2,307, Nonsense Mutation 238, Intron 188, Splice Region 70, 3'UTR 31, Splice Site 27, 5'Flank 23, 5'UTR 20, Frame Shift Del 17, RNA 16, 3'Flank 12.

Variants (750 of 7,258; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 94/324 reads (29%) | catalogued as rs397515469, CM138043; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 252/672 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918614, CM041247; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/330 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/326 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.5392+1G>A p.X1798_splice | Splice Site (SNP) | VAF 141/572 reads (25%) | catalogued as rs1557104968; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CERKL | c.1090C>T p.R364* (on ENST00000339098 / NM_001030311.2; = p.R338* on NM_201548.5) | Nonsense Mutation (SNP) | VAF 116/456 reads (25%) | catalogued as rs748394238, CM156178, COSV59203916; ClinVar: pathogenic; called by muse, varscan2
- CFTR | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs556880586, CM162714, COSV50041108; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCX | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 202/786 reads (26%) | catalogued as rs587783519, CM980518, COSV57567701, COSV57571382; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJB1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 207/861 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs879254099, CM940838; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 108/461 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDUA | c.793-1G>A p.X265_splice | Splice Site (SNP) | VAF 81/388 reads (21%) | catalogued as rs762779421; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 112/525 reads (21%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2, varscan2
- NEB | c.507+1G>A p.X169_splice | Splice Site (SNP) | VAF 60/228 reads (26%) | catalogued as rs1553689057; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 119/325 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4867C>T p.R1623* (on ENST00000333535 / NM_198056.3; = p.R1622* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 128/436 reads (29%) | catalogued as rs137854613, CD1510491, CM033022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 80/325 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- THRB | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 159/602 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121918686, CM910368, CM920668; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 78/246 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52628536; called by muse, mutect2, varscan2
- AASDH | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 88/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447962145, COSV52705900; called by muse, mutect2, varscan2
- AASS | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1004656242, COSV100741774; called by muse, mutect2, varscan2
- ABCA12 | c.1258C>T p.P420S (on ENST00000272895 / NM_173076.3; = p.P102S on NM_015657.3) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1297612225, COSV55952615; called by muse, mutect2, varscan2
- ABCA4 | c.4720G>A p.E1574K | Missense Mutation (SNP) | VAF 118/554 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as CM091659; called by muse, mutect2, varscan2
- ABCA9 | c.4798G>A p.E1600K | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV60631939; called by muse, mutect2, varscan2
- ABCB1 | c.3764G>A p.G1255D | Missense Mutation (SNP) | VAF 168/806 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013586488, COSV55961017; called by muse, varscan2
- ABCB1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs771100656; called by muse, mutect2, varscan2
- ABCB5 | c.1789G>A p.D597N (on ENST00000404938 / NM_001163941.2; = p.D152N on NM_178559.6) | Missense Mutation (SNP) | VAF 255/682 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV51716847, COSV99327794; called by muse, mutect2, varscan2
- ABCC1 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 120/484 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.772); catalogued as COSV100579367; called by muse, mutect2, varscan2
- ABCC9 | c.3605C>G p.T1202R | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM140385, COSV53978242; called by muse, mutect2, varscan2
- ABCC9 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV53981936; called by muse, mutect2, varscan2
- ABCC9 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1392861824, COSV53989364; called by muse, varscan2
- ABI2 | c.1315C>T p.P439S (on ENST00000295851 / NM_001375719.1; = p.P401S on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs757483197; called by muse, varscan2
- ABLIM2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 99/490 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs757458512; called by muse, mutect2, varscan2
- ABRACL | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 67/359 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs779344089, COSV100866320; called by muse, mutect2, varscan2
- AC005833.1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 107/396 reads (27%) | SIFT deleterious (0.01); catalogued as rs750919954, COSV52894841; called by muse, mutect2, varscan2
- AC008397.1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 121/468 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs548607816; called by muse, mutect2, varscan2
- AC008676.3 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs367831706; called by muse, mutect2, varscan2
- AC024598.1 | c.1364del p.P455Lfs*173 | Frame Shift Del (DEL) | VAF 90/313 reads (29%) | catalogued as COSV60823737; called by mutect2, pindel, varscan2
- AC119396.1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 164/614 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs746159959; called by muse, varscan2
- AC242842.3 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1321723156; called by muse, mutect2, varscan2
- ACAP1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs1296032474; called by muse, mutect2, varscan2
- ACBD7 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1313398645; called by muse, mutect2, varscan2
- ACKR4 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV51443073; called by muse, mutect2, varscan2
- ACMSD | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs148826882; called by muse, mutect2, varscan2
- ACOX3 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs762724040; called by muse, mutect2, varscan2
- ACRBP | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 117/465 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57524515; called by muse, mutect2, varscan2
- ACSM1 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV54637330, COSV54639232; called by muse, mutect2, varscan2
- ACSM2A | c.296G>A p.G99E (on ENST00000219054; = p.G20E on NM_001308169.2) | Missense Mutation (SNP) | VAF 74/1074 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99525348; called by muse, mutect2
- ACTL7A | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 97/379 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777158390, COSV100452976; called by muse, mutect2, varscan2
- ACTL9 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 126/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61006186; called by mutect2, varscan2
- ACTRT1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 125/646 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV64419240; called by muse, mutect2, varscan2
- ACVR2A | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022026; called by muse, mutect2, varscan2
- ACVR2A | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 91/386 reads (24%) | catalogued as COSV99604865; called by muse, mutect2, varscan2
- ADAM18 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55845381; called by muse, mutect2, varscan2
- ADAM22 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55990886; called by muse, mutect2, varscan2
- ADAM28 | c.228G>A p.K76= | Splice Region (SNP) | VAF 64/253 reads (25%) | catalogued as COSV56098833; called by muse, mutect2, varscan2
- ADAM29 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 90/410 reads (22%) | catalogued as rs149968346, COSV63668854; called by muse, mutect2, varscan2
- ADAM29 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 114/545 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63664722; called by muse, mutect2, varscan2
- ADAM32 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.38); catalogued as rs766436330, COSV65947294; called by muse, mutect2, varscan2
- ADAM33 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 104/430 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1343276329; called by muse, mutect2, varscan2
- ADAM7 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.301); catalogued as COSV51543398; called by muse, varscan2
- ADAM7 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV51542992; called by muse, varscan2
- ADAMDEC1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56474387; called by muse, mutect2, varscan2
- ADAMTS10 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 142/647 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV99547031; called by muse, mutect2, varscan2
- ADAMTS12 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 131/590 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV61259385; called by muse, mutect2, varscan2
- ADAMTS13 | c.2720C>T p.S907F | Missense Mutation (SNP) | VAF 121/475 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1554792426; called by muse, mutect2, varscan2
- ADAMTS20 | c.4435G>A p.A1479T | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.329); catalogued as rs1225924601; called by muse, varscan2
- ADAMTS6 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as COSV100068214; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2249G>A p.S750N | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1422289323; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2661G>A p.M887I | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54447044; called by muse, mutect2, varscan2
- ADARB1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62341921; called by muse, mutect2, varscan2
- ADCY1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 300/825 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV52042313; called by muse, mutect2, varscan2
- ADD2 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 155/529 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201864311, COSV52462087; called by muse, mutect2, varscan2
- ADD2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs782227971, COSV100035853, COSV52459390, COSV52462329; called by muse, mutect2, varscan2
- ADGB | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs1421498910; called by muse, mutect2, varscan2
- ADGRA1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 154/513 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs753948568; called by muse, mutect2, varscan2
- ADGRB1 | c.3764G>A p.R1255Q | Missense Mutation (SNP) | VAF 335/846 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs140735806; called by muse, varscan2
- ADGRB3 | c.3833G>A p.R1278Q | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs780079804, COSV99486221; called by muse, mutect2, varscan2
- ADGRB3 | c.4083G>A p.M1361I | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53251978; called by muse, varscan2
- ADGRD1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 96/471 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV55442179; called by muse, mutect2, varscan2
- ADGRD1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 129/477 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55443463; called by muse, mutect2, varscan2
- ADGRD1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1414920260, COSV99897456; called by muse, mutect2, varscan2
- ADGRE2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100216650; called by muse, mutect2, varscan2
- ADGRF2 | c.1003T>C p.S335P (on ENST00000296862 / NM_001368115.2; = p.S267P on NM_153839.7) | Missense Mutation (SNP) | VAF 87/432 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs1298487098; called by muse, mutect2, varscan2
- ADGRG5 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs993203802; called by muse, mutect2, varscan2
- ADGRL2 | c.2636G>A p.R879Q (on ENST00000370717 / NM_001366005.1; = p.R866Q on NM_012302.4) | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373312947; called by muse, varscan2
- ADGRV1 | c.3674A>G p.N1225S | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.093); catalogued as rs1427473064, COSV67995353; called by muse, mutect2, varscan2
- ADGRV1 | c.7669C>T p.Q2557* | Nonsense Mutation (SNP) | VAF 99/438 reads (23%) | catalogued as COSV67986115; called by muse, mutect2, varscan2
- ADH6 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1262841786; called by muse, mutect2, varscan2
- ADH6 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52956502; called by muse, varscan2
- ADIG | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 108/360 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1315359324; called by muse, varscan2
- ADNP2 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 145/818 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1352862103; called by muse, mutect2, varscan2
- ADRM1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 248/761 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs747481677; called by muse, mutect2, varscan2
- AGMO | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1298651599, COSV100693705; called by muse, mutect2, varscan2
- AHNAK2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 104/475 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1048400750, COSV100318622; called by muse, mutect2, varscan2
- AHR | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 185/550 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs770650129, COSV54124754; called by muse, mutect2, varscan2
- AHRR | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763810046, COSV57084808; called by muse, mutect2, varscan2
- AIFM3 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 116/443 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV53151531; called by muse, mutect2, varscan2
- AJAP1 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450477, COSV65452098; called by muse, mutect2, varscan2
- AKAP1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 252/612 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs1405680094; called by muse, mutect2, varscan2
- AKAP1 | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 137/591 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs138368517; called by muse, mutect2, varscan2
- AKR1B15 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 160/516 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs373511828; called by muse, varscan2
- AKR1D1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV54336211; called by muse, mutect2, varscan2
- AL121899.2 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 103/450 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67351449; called by muse, mutect2, varscan2
- AL121899.2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1259803578, COSV67350680; called by muse, mutect2, varscan2
- AL592490.1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 78/334 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1365085308; called by muse, mutect2, varscan2
- AL592490.1 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69428214; called by muse, mutect2, varscan2
- AL645922.1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 240/1141 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs766612461; called by muse, mutect2, varscan2
- ALK | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 140/518 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs748493584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK1 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV51586405; called by muse, mutect2, varscan2
- ALPK2 | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 134/699 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV64495215; called by muse, mutect2, varscan2
- ALPK2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 115/597 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs936645156; called by muse, mutect2, varscan2
- AMDHD1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1437041316; called by muse, mutect2, varscan2
- AMPD1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 90/428 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.909); catalogued as rs1557967800; called by muse, mutect2, varscan2
- AMY1A | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1298138855; called by muse, mutect2, varscan2
- AMY1C | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV64407211; called by muse, mutect2, varscan2
- AMY2A | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 41/448 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101340677; called by muse, mutect2
- AMY2A | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs1432363996; called by mutect2, varscan2
- ANGPT2 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs528884957; called by muse, mutect2, varscan2
- ANGPT4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1316454310; called by muse, mutect2, varscan2
- ANK1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 104/472 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs765970246; called by muse, mutect2, varscan2
- ANK2 | c.3219C>A p.F1073L | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52185380; called by muse, mutect2, varscan2
- ANKRD24 | c.3230C>T p.A1077V | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs761066513; called by muse, mutect2, varscan2
- ANKRD27 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424266918; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ANO4 | c.1460G>A p.G487E (on ENST00000392977 / NM_001286615.2; = p.G452E on NM_178826.4) | Missense Mutation (SNP) | VAF 195/573 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV54587402; called by muse, mutect2, varscan2
- ANOS1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 139/642 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV52921216; called by muse, mutect2, varscan2
- AOAH | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 75/476 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs200308661; called by muse, mutect2, varscan2
- AOAH | c.115C>G p.H39D | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV51747992; called by muse, mutect2, varscan2
- AP1M1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 101/492 reads (21%) | catalogued as COSV52230447; called by muse, mutect2, varscan2
- AP1M2 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 104/541 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV51568633; called by muse, mutect2, varscan2
- AP1M2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 106/544 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1202522150, COSV51566479, COSV51568642, COSV99140743; called by muse, mutect2, varscan2
- APAF1 | c.854C>T p.S285F (on ENST00000551964 / NM_181861.2; = p.S274F on NM_001160.3) | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV59663821; called by muse, mutect2, varscan2
- APLNR | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 117/525 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs780061917, COSV57241774, COSV57243829; called by muse, mutect2, varscan2
- APLP2 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 105/341 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775965049; called by muse, mutect2, varscan2
- APOB | c.12497G>A p.G4166E | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV51923213; called by muse, mutect2, varscan2
- APOB | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.695); catalogued as rs771182405; called by muse, mutect2, varscan2
- APOBEC3A | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 158/691 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1452311320; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 162/661 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2, varscan2
- APOH | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99235554; called by muse, mutect2, varscan2
- APOL5 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 114/542 reads (21%) | catalogued as rs568136674, COSV50767095; called by muse, mutect2, varscan2
- AQP3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 158/455 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs539666664; called by muse, mutect2, varscan2
- ARFGEF3 | c.5521C>A p.L1841I | Missense Mutation (SNP) | VAF 124/580 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV52454232; called by muse, mutect2, varscan2
- ARG1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1326930389, CM128110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP12 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 155/583 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs780233101, COSV60962231; called by muse, mutect2, varscan2
- ARHGAP36 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 200/879 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1350371224; called by muse, mutect2, varscan2
- ARHGAP39 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 194/749 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1021189843, COSV52770991; called by muse, mutect2, varscan2
- ARHGAP5 | c.4135C>T p.P1379S (on ENST00000345122 / NM_001030055.2; = p.P1378S on NM_001173.3) | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs905851462, COSV53735028, COSV53735111; called by muse, mutect2, varscan2
- ARHGEF10 | c.701C>T p.P234L (on ENST00000398564; = p.P209L on NM_014629.4) | Missense Mutation (SNP) | VAF 107/517 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV50675932; called by muse, mutect2
- ARHGEF15 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs771609829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF9 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 115/528 reads (22%) | catalogued as COSV53644363; called by muse, mutect2, varscan2
- ARID1A | c.4024C>T p.Q1342* | Nonsense Mutation (SNP) | VAF 80/384 reads (21%) | catalogued as COSV61381745; called by muse, mutect2, varscan2
- ARL5C | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 114/429 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1009967820; called by muse, mutect2, varscan2
- ARMC4 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 120/476 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59473944; called by muse, mutect2, varscan2
- ARMC5 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 199/826 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); catalogued as rs1467735332; called by muse, mutect2, varscan2
- ARMC6 | c.320C>T p.P107L (on ENST00000392336; = p.P82L on NM_033415.4) | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54184682; called by muse, mutect2, varscan2
- ARMC9 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 94/312 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63023202; called by muse, mutect2, varscan2
- ARMCX2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 146/684 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as rs1556062402; called by muse, mutect2, varscan2
- ARSG | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 108/542 reads (20%) | catalogued as COSV101477874; called by muse, varscan2
- ARVCF | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 134/497 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747809824; called by muse, mutect2, varscan2
- ASB4 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV57945785; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 131/533 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, mutect2, varscan2
- ASPHD1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 135/396 reads (34%) | catalogued as rs375012242, COSV58097226; called by muse, mutect2, varscan2
- ASTN1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.801); catalogued as rs1356115368, COSV56069844; called by muse, mutect2, varscan2
- ASXL3 | c.5044G>A p.D1682N | Missense Mutation (SNP) | VAF 104/578 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as rs1474781822; called by muse, varscan2
- ATG2A | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 119/472 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs779631331; called by muse, varscan2
- ATG2B | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 70/327 reads (21%) | catalogued as rs775509366, COSV63424831, COSV63425824; called by muse, mutect2, varscan2
- ATG4A | c.649T>G p.C217G | Missense Mutation (SNP) | VAF 155/684 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58965212; called by muse, mutect2, varscan2
- ATM | c.8719C>T p.P2907S | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53725759; called by muse, mutect2, varscan2
- ATP10B | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs774384700; called by muse, varscan2
- ATP10D | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 111/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99905126; called by muse, mutect2, varscan2
- ATP13A4 | c.2243C>T p.T748I | Missense Mutation (SNP) | VAF 118/571 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs778927180; called by muse, mutect2, varscan2
- ATP13A5 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60868641; called by muse, mutect2, varscan2
- ATP1A4 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 118/793 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625648; called by muse, mutect2, varscan2
- ATP6AP2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 139/657 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765852654; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP6V0A1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99230318; called by muse, mutect2, varscan2
- ATP7B | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017756733; called by muse, mutect2, varscan2
- ATP8A1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.023); catalogued as rs866499854, COSV100047216, COSV52548088; called by muse, mutect2, varscan2
- ATP8B1 | c.3644G>A p.R1215Q | Missense Mutation (SNP) | VAF 174/900 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.32); catalogued as rs1267956118, COSV52180803; called by muse, mutect2, varscan2
- ATP8B4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752810289, COSV52718864; called by muse, mutect2, varscan2
- ATP8B4 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs772433336, COSV99466803; called by muse, varscan2
- ATRNL1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100744032; called by muse, mutect2, varscan2
- ATRX | c.248C>G p.P83R | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64869481; called by muse, mutect2, varscan2
- AXIN2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 142/836 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1060502156, COSV61062042; ClinVar: uncertain significance; called by muse, varscan2
- AZU1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 135/615 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753330643; called by muse, mutect2, varscan2
- B3GALT1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 109/527 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs755628484, COSV59908038; called by muse, mutect2, varscan2
- BACH1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 118/361 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99728634; called by muse, mutect2, varscan2
- BAHCC1 | c.2564C>T p.S855F | Missense Mutation (SNP) | VAF 173/945 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57030932; called by muse, mutect2, varscan2
- BAHD1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 108/507 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs367799058; called by muse, mutect2, varscan2
- BBS12 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 96/475 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58562329; called by muse, mutect2, varscan2
- BCAP31 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV61452102; called by muse, mutect2, varscan2
- BCL11B | c.2318G>A p.G773E (on ENST00000357195 / NM_001282237.2; = p.G702E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/603 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV61736933; called by muse, varscan2
- BCL11B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 136/620 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as rs867773884; called by muse, mutect2, varscan2
- BCL9 | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 70/355 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV52347608; called by muse, mutect2, varscan2
- BCORL1 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 179/774 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs371566085, COSV54405839, COSV99500497; called by muse, mutect2, varscan2
- BEND2 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66216439; called by muse, mutect2, varscan2
- BEND2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 134/582 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as COSV66217571; called by muse, mutect2, varscan2
- BEND3 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 125/534 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64681284; called by muse, mutect2, varscan2
- BEND4 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 131/529 reads (25%) | catalogued as COSV72469138; called by muse, mutect2, varscan2
- BEX5 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 180/712 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61328666; called by muse, varscan2
- BFSP1 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 111/437 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs754162101; called by muse, mutect2, varscan2
- BICD1 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 97/415 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs1431570417, COSV55689989; called by muse, mutect2, varscan2
- BICRA | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 141/570 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs1264388301; called by muse, mutect2, varscan2
- BICRA | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 155/648 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs760865535, COSV101194236; called by muse, mutect2, varscan2
- BIN2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 124/571 reads (22%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs1205807137, COSV57203627; called by muse, mutect2, varscan2
- BLNK | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs782646551, COSV99814320; called by muse, mutect2, varscan2
- BLOC1S4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 101/430 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1486712240; called by muse, mutect2, varscan2
- BMP1 | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762615008; called by muse, mutect2, varscan2
- BMP10 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.179); catalogued as rs529530758; called by muse, mutect2, varscan2
- BMP5 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 111/435 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63704758; called by muse, mutect2, varscan2
- BMX | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 140/664 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs755193536; called by muse, mutect2, varscan2
- BOC | c.2593A>G p.I865V | Missense Mutation (SNP) | VAF 152/648 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1341991596, COSV56353105; called by muse, mutect2, varscan2
- BOK | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 154/679 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs372034705; called by muse, mutect2, varscan2
- BOK | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 112/585 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416884690; called by muse, mutect2, varscan2
- BPIFB6 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 172/483 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1415697016, COSV62755802; called by muse, mutect2, varscan2
- BRD4 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.018); catalogued as rs1041579791; called by muse, mutect2, varscan2
- BRD9 | c.444C>G p.F148L | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.802); catalogued as COSV51319453; called by muse, mutect2, varscan2
- BRDT | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 95/366 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100746040, COSV62865393; called by muse, mutect2, varscan2
- BRINP1 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 128/534 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs201389326, COSV56297772; called by muse, varscan2
- BRINP3 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 108/636 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.977); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRMS1L | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs1208910526, COSV53762281; called by muse, mutect2, varscan2
- BRSK1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 107/490 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs753928719, COSV58666048; called by muse, mutect2, varscan2
- BRSK2 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 155/643 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1478648131; called by muse, mutect2, varscan2
- BRSK2 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 162/660 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs745607962; called by muse, mutect2, varscan2
- BRWD3 | c.4759G>A p.G1587R | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100955513; called by muse, mutect2, varscan2
- BTAF1 | c.2713C>T p.L905F | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56435071; called by muse, mutect2, varscan2
- BTBD11 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 139/785 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs1156521801; called by muse, mutect2, varscan2
- BTBD11 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 138/778 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs1379464779, COSV99776790; called by muse, mutect2, varscan2
- BTBD3 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 123/449 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs1433924999; called by muse, mutect2, varscan2
- BTN3A2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 177/835 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62686966; called by muse, mutect2, varscan2
- BTNL8 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 97/485 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51458004; called by muse, mutect2, varscan2
- C10orf71 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 117/423 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as rs1484560930; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C12orf42 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV59381532; called by muse, mutect2, varscan2
- C17orf80 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 187/520 reads (36%) | catalogued as rs377133509; called by muse, mutect2, varscan2
- C19orf57 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 149/601 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1345080621; called by muse, mutect2, varscan2
- C1QL2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 97/416 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs372499362; called by muse, mutect2, varscan2
- C1QTNF9B | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 131/1162 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs763966278; called by muse, mutect2, varscan2
- C1S | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 123/554 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs142773314; called by muse, mutect2, varscan2
- C1orf127 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65439239; called by muse, mutect2, varscan2
- C1orf141 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV63993442; called by muse, mutect2, varscan2
- C1orf158 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 135/596 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.16); catalogued as rs764495041; called by muse, mutect2, varscan2
- C1orf87 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 127/572 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs865999347; called by muse, mutect2, varscan2
- C20orf27 | c.18G>A p.K6= | Splice Region (SNP) | VAF 110/401 reads (27%) | catalogued as rs1000416166; called by muse, mutect2, varscan2
- C2orf16 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.491); catalogued as rs959354788; called by muse, mutect2, varscan2
- C2orf78 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs770892539, COSV68517857, COSV68518024; called by muse, mutect2, varscan2
- C3 | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 128/492 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV55572340; called by muse, mutect2, varscan2
- C4B | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 88/602 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747943993; called by muse, mutect2, varscan2
- C6 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs533503397, COSV54709066; called by muse, varscan2
- C6 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs868157405, COSV99667188; called by muse, mutect2, varscan2
- C7 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100496387; called by muse, varscan2
- C8B | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV64777279; called by muse, mutect2, varscan2
- C8B | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs780551849, COSV64779655; called by muse, mutect2, varscan2
- C8B | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100980749, COSV64776859; called by muse, mutect2, varscan2
- C9 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs368001255, COSV99661547; called by muse, mutect2, varscan2
- C9orf57 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1390875458, COSV65462482; called by muse, mutect2, varscan2
- C9orf78 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 103/430 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs770685876, COSV59614045; called by muse, mutect2, varscan2
- CA2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 91/541 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV53407446; called by muse, mutect2, varscan2
- CACNA1A | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 124/586 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1383227916; called by muse, varscan2
- CACNA1E | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62410718; called by muse, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 219/564 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CACNA1E | c.4023G>A p.M1341I | Missense Mutation (SNP) | VAF 101/585 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV62402735; called by muse, mutect2, varscan2
- CACNA1E | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 101/591 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.086); catalogued as rs752972345; called by muse, mutect2, varscan2
- CACNA1E | c.6022C>T p.P2008S | Missense Mutation (SNP) | VAF 175/427 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.343); catalogued as COSV62424027; called by muse, mutect2, varscan2
- CACNA1F | c.4183G>A p.G1395R | Missense Mutation (SNP) | VAF 116/585 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370863603, COSV100544816, COSV59905779; called by muse, varscan2
- CACNA1G | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 350/818 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as rs577320837, COSV61739478; called by muse, varscan2
- CACNA1G | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 176/926 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs778481197; called by muse, mutect2, varscan2
- CACNA1H | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1238943785; called by muse, mutect2, varscan2
- CACNA1H | c.6764C>T p.S2255F | Missense Mutation (SNP) | VAF 158/704 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as rs746214213, COSV52358267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 58/291 reads (20%) | catalogued as COSV54950668; called by muse, varscan2
- CACNG2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 98/419 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100269143; called by muse, mutect2, varscan2
- CACNG4 | c.714C>G p.Y238* | Nonsense Mutation (SNP) | VAF 132/646 reads (20%) | catalogued as COSV50927933; called by muse, mutect2, varscan2
- CACNG4 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 131/640 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs767219625; called by muse, mutect2, varscan2
- CACNG7 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV55817202; called by muse, mutect2, varscan2
- CAGE1 | c.1615G>A p.E539K (on ENST00000512086; = p.E403K on NM_205864.3) | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1482505651, COSV57074979; called by muse, mutect2, varscan2
- CAGE1 | c.724G>A p.E242K (on ENST00000512086; = p.E106K on NM_205864.3) | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99699467; called by muse, varscan2
- CALCRL | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV66476639; called by muse, mutect2, varscan2
- CAPN11 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 114/551 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67238307, COSV67239933; called by muse, mutect2, varscan2
- CAPN15 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 116/473 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as rs781378615, COSV99562383; called by muse, mutect2, varscan2
- CAPSL | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 126/499 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as COSV68438824; called by muse, mutect2, varscan2
- CAPSL | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 68/352 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs145854210, COSV68437721; called by muse, mutect2
- CARD10 | c.2702C>T p.T901I | Missense Mutation (SNP) | VAF 118/500 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1442162760, COSV52658200; called by muse, mutect2, varscan2
- CARD11 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs778162676, COSV62754024, COSV62757152; called by muse, mutect2, varscan2
- CASC3 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs559102541; called by muse, mutect2, varscan2
- CASC3 | c.1970C>G p.P657R | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52868691; called by muse, varscan2
- CASP3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1457645538, COSV57724877; called by muse, mutect2, varscan2
- CASR | c.2854G>A p.E952K (on ENST00000490131; = p.E1029K on NM_000388.4) | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV56141462; called by muse, mutect2, varscan2
- CASS4 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 114/624 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV64385671; called by muse, mutect2, varscan2
- CATSPER2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58660523; called by muse, mutect2, varscan2
- CATSPERB | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 92/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866512933, COSV56426913; called by muse, varscan2
- CATSPERD | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV67534863; called by muse, mutect2, varscan2
- CBX4 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 249/1088 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV53965641; called by muse, mutect2, varscan2
- CCBE1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 247/677 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs537637686, COSV67951527; called by muse, mutect2, varscan2
- CCDC105 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV52963797; called by muse, mutect2, varscan2
- CCDC141 | c.2903C>T p.T968I | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as rs1349350537; called by muse, mutect2, varscan2
- CCDC158 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 157/597 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV66357172; called by muse, mutect2, varscan2
- CCDC38 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs866024502; called by muse, mutect2, varscan2
- CCDC63 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 217/619 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57526812; called by muse, mutect2, varscan2
- CCDC8 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs1184808985; called by muse, mutect2, varscan2
- CCDC81 | c.1489C>T p.R497W (on ENST00000445632 / NM_001156474.2; = p.R407W on NM_021827.4) | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.44); catalogued as rs770021383; called by muse, mutect2, varscan2
- CCDC88C | c.5225G>A p.G1742E | Missense Mutation (SNP) | VAF 155/689 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as rs774327623, COSV57795968; called by muse, mutect2, varscan2
- CCDC88C | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs979734927; called by muse, mutect2, varscan2
- CCER1 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 202/845 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV62646095; called by muse, mutect2, varscan2
- CCKAR | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 154/585 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.649); catalogued as COSV99810381; called by muse, mutect2, varscan2
- CCR9 | c.475G>A p.E159K (on ENST00000357632 / NM_031200.3; = p.E147K on NM_006641.4) | Missense Mutation (SNP) | VAF 117/514 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62940957; called by muse, mutect2, varscan2
- CCRL2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 116/513 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs755483032, COSV99050934; called by muse, mutect2, varscan2
- CD163 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 103/509 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV63129186; called by muse, mutect2, varscan2
- CD163 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 82/390 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV63136065; called by muse, mutect2, varscan2
- CD163 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 102/442 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1026634528, COSV100776194; called by muse, varscan2
- CD163 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100775982; called by muse, mutect2, varscan2
- CD163L1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 101/533 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV100549799; called by muse, mutect2, varscan2
- CD163L1 | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 129/584 reads (22%) | catalogued as rs1195394852; called by muse, mutect2, varscan2
- CD1B | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 200/568 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV63803723; called by muse, mutect2, varscan2
- CD1D | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 200/574 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750887347, COSV63808719; called by muse, mutect2, varscan2
- CD207 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); catalogued as COSV69652271; called by muse, mutect2, varscan2
- CD300C | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 67/453 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV58169913; called by muse, mutect2, varscan2
- CD300LG | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 100/497 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1400061735, COSV53222498; called by muse, mutect2, varscan2
- CD300LG | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 120/446 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs776973565; called by muse, mutect2, varscan2
- CD79B | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 119/574 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746592632, COSV50082933; called by muse, mutect2, varscan2
- CD93 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 146/615 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs781629298; called by muse, mutect2, varscan2
- CD93 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 123/580 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.687); catalogued as COSV55665211; called by muse, varscan2
- CD96 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.526); catalogued as rs1452862245, COSV51922979; called by muse, mutect2, varscan2
- CDCP1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 134/650 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.189); catalogued as COSV56107955; called by muse, mutect2, varscan2
- CDH10 | c.2198T>G p.L733R | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050052; called by muse, mutect2, varscan2
- CDH12 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 108/508 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV66454662; called by muse, mutect2, varscan2
- CDH13 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs765363332; called by muse, mutect2, varscan2
- CDH18 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 120/489 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as rs866875588, COSV56959856; called by muse, mutect2, varscan2
- CDH20 | c.2052G>A p.W684* | Nonsense Mutation (SNP) | VAF 160/925 reads (17%) | catalogued as COSV99404759, COSV99405536; called by muse, mutect2, varscan2
- CDH22 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 209/647 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.572); catalogued as rs747666399; called by muse, mutect2, varscan2
- CDH22 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 118/576 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376559927; called by muse, varscan2
- CDH4 | c.2245G>A p.V749I | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs1212472736; called by muse, mutect2, varscan2
- CDH5 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.781); catalogued as rs891727598; called by muse, mutect2, varscan2
- CDH6 | c.804C>G p.F268L | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs998808279; called by muse, mutect2
- CDH6 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 61/336 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV54067361; called by muse, mutect2
- CDH9 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 133/478 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs267600596, COSV50253768; called by muse, mutect2, varscan2
- CDK18 | c.557C>T p.A186V (on ENST00000506784 / NM_212503.3; = p.A156V on NM_002596.4) | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1453869920; called by muse, mutect2, varscan2
- CDK19 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60453097; called by muse, mutect2, varscan2
- CDK5 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 131/639 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV99877555; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs746903524, COSV62571997; called by muse, mutect2, varscan2
- CDKL5 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1479054834, COSV66105925, COSV66106560; called by muse, mutect2, varscan2
- CEACAM1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 152/624 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs768241278, COSV50732690; called by muse, mutect2, varscan2
- CEACAM18 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV67284093; called by muse, mutect2
- CEACAM18 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 123/442 reads (28%) | catalogued as rs572936413, COSV67282772; called by muse, mutect2, varscan2
- CEACAM7 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV50074479; called by muse, mutect2, varscan2
- CEBPG | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 137/551 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs760801673; called by muse, mutect2, varscan2
- CELA3A | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 108/679 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1442695696; called by muse, varscan2
- CELA3A | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV51585956; called by muse, mutect2, varscan2
- CELA3B | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 123/588 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV61404417; called by muse, mutect2, varscan2
- CELSR1 | c.5476G>A p.A1826T | Missense Mutation (SNP) | VAF 140/494 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs368381807; called by muse, mutect2, varscan2
- CELSR2 | c.5792C>T p.S1931F | Missense Mutation (SNP) | VAF 178/648 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54766104; called by muse, mutect2, varscan2
- CELSR3 | c.6988C>T p.R2330C | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs574950617; called by muse, mutect2, varscan2
- CEMIP | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1434869560; called by muse, mutect2, varscan2
- CEMIP2 | c.3767C>T p.P1256L | Missense Mutation (SNP) | VAF 147/603 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV100987383; called by muse, mutect2, varscan2
- CENPJ | c.3742C>G p.P1248A | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99692415; called by muse, mutect2, varscan2
- CEP350 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 91/473 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1167393402; called by muse, mutect2, varscan2
- CER1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 134/419 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV66603115; called by muse, mutect2, varscan2
- CERKL | c.1124C>T p.A375V (on ENST00000339098 / NM_001030311.2; = p.A349V on NM_201548.5) | Missense Mutation (SNP) | VAF 68/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59204987; called by muse, varscan2
- CETN1 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 136/542 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV59121357; called by muse, mutect2, varscan2
- CETN1 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 138/585 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV59122123; called by muse, mutect2, varscan2
- CFAP43 | c.584+1G>A p.X195_splice | Splice Site (SNP) | VAF 76/202 reads (38%) | catalogued as rs1262736589; called by muse, mutect2, varscan2
- CFAP44 | c.3070C>T p.R1024* | Nonsense Mutation (SNP) | VAF 50/210 reads (24%) | catalogued as rs921491856, COSV67249394; called by muse, mutect2, varscan2
- CFAP46 | c.6771G>C p.E2257D | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV54150308; called by muse, mutect2, varscan2
- CFAP47 | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs748173415, COSV100545776, COSV57971660; called by muse, mutect2, varscan2
- CFAP54 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs145849236; called by muse, mutect2, varscan2
- CFAP54 | c.6419G>A p.G2140E | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61573137; called by muse, mutect2, varscan2
- CFAP54 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV61573171; called by muse, mutect2, varscan2
- CFAP57 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 109/483 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV65264954; called by muse, mutect2, varscan2
- CFH | c.2103G>A p.W701* | Nonsense Mutation (SNP) | VAF 138/371 reads (37%) | catalogued as CM1510266, COSV66407241; called by muse, mutect2, varscan2
- CFH | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV66414666; called by muse, mutect2, varscan2
- CFHR3 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV66401728; called by muse, mutect2, varscan2
- CFHR5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56820648; called by muse, mutect2, varscan2
- CFHR5 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56817785; called by muse, mutect2, varscan2
- CGB1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 151/812 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as COSV99041410; called by muse, varscan2
- CHD6 | c.7472C>T p.P2491L | Missense Mutation (SNP) | VAF 220/604 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1310794292, COSV64690969; called by muse, varscan2
- CHD6 | c.7360C>T p.P2454S | Missense Mutation (SNP) | VAF 140/590 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs539039219, COSV64689947; called by muse, varscan2
- CHD8 | c.4684C>T p.Q1562* (on ENST00000646647 / NM_001170629.2; = p.Q1283* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 103/445 reads (23%) | catalogued as rs1555314263, COSV63219509; called by muse, mutect2, varscan2
- CHGB | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 113/555 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66762019; called by muse, mutect2, varscan2
- CHL1 | c.2210C>T p.S737F (on ENST00000397491 / NM_001253387.1; = p.S753F on NM_006614.4) | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs756724772; called by muse, mutect2, varscan2
- CHRNA2 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 99/497 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as rs1165713402; called by muse, mutect2, varscan2
- CHRNA5 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV55138006; called by muse, mutect2, varscan2
- CHRNB3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs1173756143, COSV51497847; called by muse, mutect2, varscan2
- CHRNG | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 154/474 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.17); catalogued as rs1356150480; called by muse, mutect2, varscan2
- CIDEA | c.183G>A p.K61= | Splice Region (SNP) | VAF 90/249 reads (36%) | catalogued as COSV57601174; called by muse, mutect2, varscan2
- CIDEC | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 160/698 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs956988245; called by muse, mutect2, varscan2
- CLCN1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 230/625 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546411827, CM110920, COSV58368188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN1 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 111/576 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs886062035, COSV58371742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN5 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 140/596 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56585989; called by muse, mutect2, varscan2
- CLDN19 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 185/722 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.71); catalogued as rs1259589527; called by muse, mutect2, varscan2
- CLEC12A | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1416061009; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 137/348 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, varscan2
- CLECL1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100590089; called by muse, mutect2, varscan2
- CLIC2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 117/530 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58938619; called by muse, mutect2, varscan2
- CLIC3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 157/610 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65406942; called by muse, mutect2, varscan2
- CLN8 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 128/617 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177602057; called by muse, mutect2, varscan2
- CLSTN2 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV71721096, COSV71723384; called by muse, mutect2, varscan2
- CMC1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603072; called by muse, mutect2, varscan2
- CMTM5 | c.554G>A p.G185E (on ENST00000339180 / NM_001288746.2; = p.G118E on NM_138460.3) | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59305103; called by muse, mutect2, varscan2
- CMTR1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 108/489 reads (22%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.025); catalogued as rs771887959; called by muse, mutect2, varscan2
- CMYA5 | c.4276C>T p.P1426S | Missense Mutation (SNP) | VAF 104/441 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as rs1561208578, COSV71405324; called by muse, mutect2, varscan2
- CMYA5 | c.8818C>T p.Q2940* | Nonsense Mutation (SNP) | VAF 117/479 reads (24%) | catalogued as rs571512200, COSV71405932; called by muse, mutect2, varscan2
- CNBD1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 115/319 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as rs572728867; called by muse, mutect2, varscan2
- CNGB3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 102/557 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772140410, COSV60687848; called by muse, mutect2, varscan2
- CNIH3 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs1221043867; called by muse, mutect2, varscan2
- CNR2 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100991641; called by muse, mutect2
- CNR2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as rs1442272482; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- CNTNAP4 | c.3664C>T p.H1222Y | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.642); catalogued as COSV56690176; called by muse, mutect2, varscan2
- COL11A1 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100617958; called by muse, mutect2, varscan2
- COL11A2 | c.2674G>A p.G892R (on ENST00000341947 / NM_080680.3; = p.G785R on NM_080679.2) | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59502934; called by muse, mutect2, varscan2
- COL11A2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 178/947 reads (19%) | catalogued as COSV59495804; called by muse, mutect2
- COL12A1 | c.6913C>T p.P2305S | Missense Mutation (SNP) | VAF 107/512 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100486008; called by muse, mutect2, varscan2
- COL14A1 | c.4345C>T p.H1449Y | Missense Mutation (SNP) | VAF 225/562 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV52850004; called by muse, mutect2, varscan2
- COL14A1 | c.5105G>A p.G1702E | Missense Mutation (SNP) | VAF 86/507 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52850614; called by muse, mutect2, varscan2
- COL17A1 | c.2837G>A p.G946E | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as rs1336685064, COSV62229143; called by muse, mutect2, varscan2
- COL1A1 | c.2830G>C p.G944R | Missense Mutation (SNP) | VAF 110/556 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM070773; called by muse, mutect2, varscan2
- COL1A1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 124/590 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as rs997295808; called by muse, mutect2, varscan2
- COL1A1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 125/708 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs867252794; called by muse, mutect2, varscan2
- COL1A2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72656378, CM960325; called by muse, mutect2, varscan2
- COL1A2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.603); catalogued as rs747250303; called by muse, mutect2, varscan2
- COL1A2 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 169/517 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51967877; called by muse, mutect2, varscan2
- COL20A1 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV58924717; called by muse, mutect2, varscan2
- COL21A1 | c.1650+1G>A p.X550_splice | Splice Site (SNP) | VAF 46/261 reads (18%) | catalogued as rs767901816; called by muse, mutect2, varscan2
- COL21A1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1371785735; called by muse, mutect2, varscan2
- COL21A1 | c.205A>T p.I69L | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV55170522; called by muse, mutect2, varscan2
- COL22A1 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57344495; called by muse, mutect2, varscan2
- COL22A1 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 166/520 reads (32%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs1258781634; called by muse, mutect2, varscan2
- COL22A1 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 96/580 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV57356234; called by muse, mutect2, varscan2
- COL27A1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 156/650 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs555851955; called by muse, mutect2, varscan2
- COL28A1 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 169/467 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68081586; called by muse, mutect2, varscan2
- COL3A1 | c.2451G>C p.Q817H | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV58589960; called by muse, mutect2, varscan2
- COL4A2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 209/392 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as rs1022756703, COSV64626940; called by muse, mutect2, varscan2
- COL4A3 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170596; called by muse, mutect2, varscan2
- COL4A4 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 133/520 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.406); catalogued as COSV61633711; called by muse, mutect2, varscan2
- COL4A4 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295713821, CM1312563, COSV61637153; called by muse, mutect2, varscan2
- COL4A4 | c.2604G>A p.M868I | Missense Mutation (SNP) | VAF 152/680 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as COSV61630422; called by muse, mutect2, varscan2
- COL4A4 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 103/393 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV61629823; called by muse, mutect2, varscan2
- COL4A4 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 117/488 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61630005; called by muse, mutect2, varscan2
- COL4A5 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60356628; called by muse, mutect2, varscan2
- COL4A5 | c.3646C>T p.P1216S | Missense Mutation (SNP) | VAF 118/590 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs760952344, COSV60359547; called by muse, mutect2, varscan2
- COL4A5 | c.3647C>T p.P1216L | Missense Mutation (SNP) | VAF 119/596 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1456370485, CD961923; called by muse, mutect2, varscan2
- COL4A6 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 136/578 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57865730; called by muse, mutect2, varscan2
- COL5A2 | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 97/506 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV66408193, COSV66409338; called by muse, mutect2, varscan2
- COL5A3 | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 116/472 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs745618581, COSV53413009; called by muse, varscan2
- COL6A5 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 93/432 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55194634; called by muse, mutect2, varscan2
- COL6A5 | c.4592G>A p.G1531E | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55209997; called by muse, mutect2, varscan2
- COL6A6 | c.4544G>A p.G1515E | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62031817; called by muse, mutect2, varscan2
- COL9A1 | c.2555G>A p.G852D | Missense Mutation (SNP) | VAF 95/469 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57885689; called by muse, mutect2, varscan2
- COL9A1 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 131/548 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs1305032403; called by mutect2, varscan2
- COL9A1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100295345; called by muse, mutect2, varscan2
- COL9A3 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 248/649 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); catalogued as rs527349987; called by muse, mutect2, varscan2
- COLQ | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs749266800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54101536; called by muse, mutect2, varscan2
- COX10 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 87/280 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs760154279, COSV99886779; called by muse, mutect2, varscan2
- CPA2 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 211/535 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1275564346, COSV55981671; called by muse, mutect2, varscan2
- CPA5 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 169/493 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs782787226, COSV100812506; called by muse, mutect2, varscan2
- CPAMD8 | c.3241G>A p.E1081K (on ENST00000651564; = p.E1034K on NM_015692.5) | Missense Mutation (SNP) | VAF 123/535 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71596439; called by muse, mutect2, varscan2
- CPAMD8 | c.2578G>A p.A860T (on ENST00000651564; = p.A813T on NM_015692.5) | Missense Mutation (SNP) | VAF 132/507 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs756903738, COSV101488380; called by muse, mutect2, varscan2
- CPEB1 | c.301G>A p.D101N (on ENST00000617958; = p.D41N on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/547 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as COSV71604594; called by muse, mutect2, varscan2
- CPED1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 133/620 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201993865, COSV60002594; called by muse, mutect2, varscan2
- CPS1 | c.3733C>T p.L1245F | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51817311; called by muse, mutect2, varscan2
- CPXCR1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 132/630 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52164333; called by muse, varscan2
- CPXCR1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 108/548 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV99341885; called by muse, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CPZ | c.640G>A p.G214R (on ENST00000360986 / NM_001014447.3; = p.G203R on NM_003652.3) | Missense Mutation (SNP) | VAF 186/722 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs749305362; called by muse, mutect2, varscan2
- CR1 | c.5124G>A p.V1708= | Splice Region (SNP) | VAF 76/220 reads (35%) | catalogued as rs1379163840; called by muse, mutect2, varscan2
- CR1L | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 87/529 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54328064; called by muse, mutect2, varscan2
- CRACR2A | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 131/588 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as rs1218659254; called by muse, mutect2, varscan2
- CRB1 | c.3274G>A p.G1092S | Missense Mutation (SNP) | VAF 140/462 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.926); catalogued as rs1402562231; called by muse, mutect2, varscan2
- CRB1 | c.3418T>G p.L1140V | Missense Mutation (SNP) | VAF 83/454 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs201380452; called by muse, mutect2, varscan2
- CRH | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 119/711 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as COSV52542615; called by muse, mutect2, varscan2
- CRIM1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs141894588; called by muse, mutect2, varscan2
- CRPPA | c.845C>T p.S282F (on ENST00000407010 / NM_001368197.1; = p.S232F on NM_001101417.4) | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1187330759, COSV67907310; called by muse, mutect2, varscan2
- CRYBG1 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs779714593; called by muse, mutect2, varscan2
- CRYZL1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764757517; called by muse, mutect2, varscan2
- CSH2 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 74/598 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs548290170; called by muse, mutect2, varscan2
- CSHL1 | c.306C>T p.S102= (on ENST00000309894 / NM_022581.3; = p.S8= on NM_001318.4) | Splice Region (SNP) | VAF 100/472 reads (21%) | catalogued as rs748460636, COSV99367985; called by muse, mutect2, varscan2
- CSMD1 | c.1600C>T p.P534S (on ENST00000520002; = p.P533S on NM_033225.6) | Missense Mutation (SNP) | VAF 94/375 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763319871, COSV59333498, COSV59344836; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, mutect2, varscan2
- CSMD2 | c.9830C>T p.S3277F | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53935568; called by muse, mutect2, varscan2
- CSMD2 | c.6614C>T p.S2205F | Missense Mutation (SNP) | VAF 110/562 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as COSV53879239; called by muse, mutect2, varscan2
- CSMD2 | c.4498C>T p.H1500Y | Missense Mutation (SNP) | VAF 97/411 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV53964406; called by muse, mutect2, varscan2
- CSMD2 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 112/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53897813; called by muse, varscan2
- CSMD2 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 134/549 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs778609753; called by muse, mutect2, varscan2
- CSMD2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV53914797; called by muse, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 202/578 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CSMD3 | c.8669G>A p.G2890E (on ENST00000297405 / NM_001363185.1; = p.G2721E on NM_052900.3) | Missense Mutation (SNP) | VAF 170/503 reads (34%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.999); catalogued as COSV52107666; called by muse, mutect2, varscan2
- CSMD3 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 110/564 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV99843764; called by muse, mutect2, varscan2
- CSNKA2IP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 96/379 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs935252709, COSV68072668; called by muse, mutect2, varscan2
- CSNKA2IP | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1307377510; called by muse, mutect2, varscan2
- CSNKA2IP | c.2045C>G p.S682C | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51231786; called by muse, mutect2, varscan2
- CSRNP3 | c.894C>G p.H298Q | Missense Mutation (SNP) | VAF 118/499 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV100085074; called by muse, mutect2, varscan2
- CST9L | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866228123, COSV65407576; called by muse, mutect2, varscan2
- CT47B1 | c.771del p.E258Rfs*36 | Frame Shift Del (DEL) | VAF 78/379 reads (21%) | catalogued as COSV64890971; called by pindel, varscan2
- CT47B1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 96/440 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.486); catalogued as COSV64890735, COSV64891170; called by muse, varscan2
- CT47B1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 196/886 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs757180721; called by mutect2, varscan2
- CT83 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 116/593 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781838860, COSV64140914, COSV64141554; called by muse, mutect2, varscan2
- CTAGE15 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 158/1082 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV69481964; called by muse, varscan2
- CTNND2 | c.3356G>A p.G1119E | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1369526829, COSV58868352; called by muse, varscan2
- CTSC | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 105/492 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs1312227764; called by muse, mutect2, varscan2
- CTSV | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 141/528 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52345603; called by muse, mutect2, varscan2
- CUL4B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 170/632 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV100340092; called by muse, mutect2, varscan2
- CXCL14 | c.310G>A p.E104K (on ENST00000337225; = p.E92K on NM_004887.5) | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.695); catalogued as rs754024461, COSV61499420; called by muse, mutect2, varscan2
- CXCL16 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs951948450; called by mutect2, varscan2
- CXCR2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV59281698; called by muse, mutect2, varscan2
- CYP11A1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 137/654 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs370465035, COSV99166074; called by muse, mutect2, varscan2
- CYP1A2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 136/599 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376179316; called by muse, mutect2, varscan2
- CYP24A1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 81/439 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53773054; called by muse, mutect2, varscan2
- CYP2A7 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52499541; called by muse, mutect2, varscan2
- CYP2J2 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 112/445 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757548642, COSV100968004; called by muse, mutect2, varscan2
- CYP4F2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 140/757 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.336); catalogued as COSV55616655; called by muse, mutect2, varscan2
- CYP4F2 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV99171138; called by muse, mutect2, varscan2
- CYP4Z1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs868399298, COSV61964879; called by muse, mutect2, varscan2
- D2HGDH | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV58323426; called by muse, mutect2, varscan2
- D2HGDH | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 92/416 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58323108; called by muse, mutect2, varscan2
- DAB1 | c.1657G>A p.E553K (on ENST00000371231; = p.E520K on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.461); catalogued as rs142236626; called by muse, mutect2, varscan2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DACT3 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 99/383 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV56258564; called by muse, mutect2, varscan2
- DBX2 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 96/475 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60338707; called by muse, mutect2, varscan2
- DCAF4L2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 167/444 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs867797191, COSV60477583; called by muse, mutect2, varscan2
- DCAF8L2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 127/637 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV70548728; called by muse, mutect2, varscan2
- DCAF8L2 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 130/530 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV70549666; called by muse, mutect2, varscan2
- DDHD2 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 102/389 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559842540; called by muse, mutect2, varscan2
- DDX10 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59433397; called by muse, mutect2, varscan2
- DDX19A | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156424; called by muse, mutect2, varscan2
- DDX60 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 79/398 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV67097018; called by muse, mutect2, varscan2
- DDX60 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1029134212; called by muse, mutect2, varscan2
- DEFB115 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 87/338 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs755655392; called by muse, mutect2, varscan2
- DEFB125 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.264); catalogued as COSV66703394; called by muse, mutect2, varscan2
- DENND11 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 129/416 reads (31%) | catalogued as rs1344071256, COSV72097751; called by muse, mutect2, varscan2
- DENND2C | c.1667G>A p.S556N (on ENST00000393274 / NM_001256404.2; = p.S499N on NM_198459.4) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456271075; called by muse, mutect2, varscan2
- DERPC | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 94/283 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); catalogued as rs1421736984; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DGKB | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 68/468 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1196598454; called by muse, mutect2, varscan2
- DGKG | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 148/623 reads (24%) | catalogued as rs1482297454; called by muse, mutect2, varscan2
- DGKK | c.1848G>A p.W616* | Nonsense Mutation (SNP) | VAF 97/368 reads (26%) | catalogued as COSV65709098, COSV65709716; called by muse, mutect2, varscan2
- DHRS4L2 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 124/679 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs557269720; called by muse, mutect2, varscan2
- DHTKD1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765880983; called by muse, mutect2, varscan2
- DHX15 | c.1508T>G p.L503W | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61026423; called by muse, mutect2, varscan2
- DIAPH1 | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 108/478 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as COSV53881911; called by muse, mutect2, varscan2
- DIAPH1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as rs1452397026; called by muse, mutect2, varscan2
- DIAPH1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.857); catalogued as rs771963258; called by muse, mutect2, varscan2
- DIO2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1212173092, COSV70445539; called by muse, mutect2, varscan2
- DIP2B | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 125/555 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as rs769310323, COSV56588034; called by muse, mutect2, varscan2
- DIRAS2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV101005815; called by muse, varscan2
- DKK2 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 104/460 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758106890, COSV53404374; called by muse, mutect2, varscan2
- DKK2 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 104/456 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs1250492299, COSV99568032; called by muse, mutect2, varscan2
- DLEC1 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 89/376 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs371872302; called by muse, mutect2, varscan2
- DLG2 | c.332C>G p.S111* (on ENST00000650630 / NM_001351274.2; = p.S74* on NM_001142699.3) | Nonsense Mutation (SNP) | VAF 41/250 reads (16%) | catalogued as rs550659978; called by muse, mutect2, varscan2
- DLG3 | c.1657G>A p.G553R (on ENST00000374360 / NM_021120.4; = p.G216R on NM_020730.3) | Missense Mutation (SNP) | VAF 135/525 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1000766823, COSV52083323; called by muse, mutect2, varscan2
- DLL3 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 166/590 reads (28%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as COSV99219301; called by muse, mutect2, varscan2
- DLX5 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 151/728 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as rs145966633, COSV99756458; called by muse, mutect2, varscan2
- DMD | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 122/508 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV100820252; called by muse, varscan2
- DMD | c.3087G>A p.W1029* | Nonsense Mutation (SNP) | VAF 140/545 reads (26%) | catalogued as rs398123921, CM098392; called by muse, mutect2, varscan2
- DMP1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 155/570 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142880465; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMRTA2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 143/584 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.617); catalogued as rs1337882306; called by muse, mutect2, varscan2
- DMRTC2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 123/521 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs1555836313; called by muse, mutect2, varscan2
- DMWD | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 158/727 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV52174880; called by muse, mutect2, varscan2
- DMXL1 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 117/499 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV100224504; called by muse, mutect2, varscan2
- DMXL2 | c.3487C>T p.P1163S | Missense Mutation (SNP) | VAF 105/462 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV51846724; called by muse, mutect2, varscan2
- DMXL2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773077978, COSV51857824; called by muse, mutect2, varscan2
- DNAAF6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV100314624; called by muse, mutect2, varscan2
- DNAH1 | c.4028C>T p.T1343I | Missense Mutation (SNP) | VAF 119/553 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1476992337; called by muse, mutect2, varscan2
- DNAH11 | c.5470C>T p.P1824S | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60953280; called by muse, mutect2, varscan2
- DNAH12 | c.2838G>A p.M946I (on ENST00000351747; = p.M969I on NM_001366028.2) | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV61065312; called by muse, mutect2, varscan2
- DNAH12 | c.99T>A p.D33E | Missense Mutation (SNP) | VAF 126/535 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs769307965, COSV60856040; called by muse, mutect2, varscan2
- DNAH14 | c.4123C>T p.P1375S (on ENST00000445597; = p.P1780S on NM_001367479.1) | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60737549; called by muse, mutect2, varscan2
- DNAH14 | c.6139G>A p.E2047K (on ENST00000445597; = p.E2700K on NM_001367479.1) | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1156837640, COSV59894733; called by muse, mutect2, varscan2
- DNAH14 | c.7957G>A p.E2653K (on ENST00000445597; = p.E3456K on NM_001367479.1) | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV59898531; called by muse, mutect2, varscan2
- DNAH14 | c.8053G>A p.E2685K (on ENST00000445597; = p.E3488K on NM_001367479.1) | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs917132485, COSV59898014; called by muse, mutect2, varscan2
- DNAH17 | c.3232C>T p.R1078W | Missense Mutation (SNP) | VAF 115/592 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs766370349; called by muse, varscan2
- DNAH3 | c.8863G>A p.E2955K | Missense Mutation (SNP) | VAF 136/571 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54506197; called by muse, mutect2, varscan2
- DNAH3 | c.8587T>C p.F2863L | Missense Mutation (SNP) | VAF 117/525 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV54540457; called by muse, mutect2, varscan2
- DNAH3 | c.6581G>A p.G2194E | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768942597; called by mutect2, varscan2
- DNAH5 | c.11665G>A p.E3889K | Missense Mutation (SNP) | VAF 108/519 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1263116606, COSV54242803; called by muse, mutect2, varscan2
- DNAH5 | c.10645G>A p.E3549K | Missense Mutation (SNP) | VAF 97/450 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs267600360, COSV54210342; called by muse, mutect2, varscan2
- DNAH5 | c.6628C>T p.P2210S | Missense Mutation (SNP) | VAF 99/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759065820, COSV99443507; called by muse, mutect2, varscan2
- DNAH5 | c.5143C>T p.P1715S | Missense Mutation (SNP) | VAF 99/373 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866319812, COSV99453428; called by muse, mutect2, varscan2
- DNAH5 | c.4489G>A p.E1497K | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV54243119; called by muse, varscan2
- DNAH5 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1561477933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2908C>T p.L970F | Missense Mutation (SNP) | VAF 114/469 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs1336360020, COSV54238228; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DNAH6 | c.3785G>A p.G1262E | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs901098985; called by muse, mutect2, varscan2
- DNAH6 | c.9926C>T p.S3309L | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1013401110; called by muse, mutect2, varscan2
- DNAH7 | c.9980C>T p.S3327F | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748580627, COSV56788832; called by muse, mutect2, varscan2
- DNAH7 | c.8512C>T p.L2838F | Missense Mutation (SNP) | VAF 113/496 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56792612; called by muse, mutect2, varscan2
- DNAH7 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV56751791, COSV56754965; called by muse, mutect2, varscan2
- DNAH8 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs553696622, COSV59424479, COSV59447457; called by muse, mutect2, varscan2
- DNAH8 | c.9856G>C p.E3286Q | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59481563; called by muse, mutect2, varscan2
- DNAH8 | c.12199G>A p.G4067S | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59430598; called by muse, mutect2, varscan2
- DNAH9 | c.6295C>T p.P2099S | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs149674795; called by muse, mutect2, varscan2
- DNAJB1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 117/497 reads (24%) | catalogued as COSV99584272; called by muse, mutect2, varscan2
- DNAJC18 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1047004381, COSV57415915; called by muse, mutect2, varscan2
- DNASE2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs559395836; called by muse, mutect2, varscan2
- DNM3 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 131/427 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV62467672; called by muse, mutect2, varscan2
- DNM3 | c.2149G>A p.E717K (on ENST00000355305 / NM_001350206.2; = p.E711K on NM_015569.5) | Missense Mutation (SNP) | VAF 179/492 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs267598167; called by muse, mutect2, varscan2
- DOCK1 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1187388499, COSV54747982; called by muse, mutect2, varscan2
- DOCK2 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as rs944315319, COSV56941398; called by muse, mutect2, varscan2
- DOCK3 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56514475; called by muse, varscan2
- DOCK3 | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188958196; called by muse, mutect2, varscan2
- DOK6 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 82/420 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1242540036; called by muse, mutect2, varscan2
- DPEP1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769438729; called by muse, mutect2, varscan2
- DPP3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV64756679; called by muse, mutect2, varscan2
- DPPA3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.049); catalogued as COSV61502894; called by muse, mutect2, varscan2
- DPYD | c.3052C>G p.P1018A | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs956842768; called by muse, mutect2, varscan2
- DRD3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs76849972; called by muse, mutect2, varscan2
- DRD5 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1238222021; called by muse, mutect2, varscan2
- DROSHA | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs267600599, COSV60776213; called by muse, mutect2, varscan2
- DSC1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 89/581 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57146973; called by muse, mutect2, varscan2
- DSC1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 46/309 reads (15%) | catalogued as rs765867185, COSV57147651; called by muse, mutect2, varscan2
- DSG1 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 166/483 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs146862520; called by muse, mutect2, varscan2
- DSG1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57138758; called by muse, mutect2, varscan2
- DSG1 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 184/524 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57138627; called by muse, mutect2, varscan2
- DSG1 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 242/597 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1296798214, COSV57138813; called by muse, mutect2, varscan2
- DSG2 | c.2035G>A p.G679S | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs756896076; called by muse, varscan2
- DSG2 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 153/428 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1347694586, CD061400, COSV99853414; called by muse, varscan2
- DSG3 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 124/568 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416916823; called by muse, mutect2, varscan2
- DSG4 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 78/551 reads (14%) | catalogued as rs763569094, COSV57388581, COSV57389351; called by muse, varscan2
- DSG4 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 127/361 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs74896702, COSV57388260, COSV57388919; called by muse, mutect2, varscan2
- DSG4 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 249/644 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.049); catalogued as rs774744400; called by muse, mutect2, varscan2
- DSP | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 146/606 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs1262533485, COSV65791628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 121/646 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV65793366; called by muse, mutect2, varscan2
- DTX2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 80/629 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56858707; called by muse, mutect2, varscan2
- DUOX2 | c.3917C>T p.A1306V | Missense Mutation (SNP) | VAF 134/497 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV101199604; called by muse, mutect2, varscan2
- DVL3 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 161/639 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs760819076; called by muse, mutect2, varscan2
- DYNC2H1 | c.10702C>T p.Q3568* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | catalogued as rs533399242; called by muse, mutect2, varscan2
- DYRK1A | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1430485659, COSV58293110; called by muse, mutect2, varscan2
- EBF1 | c.1744+1G>A p.X582_splice | Splice Site (SNP) | VAF 82/340 reads (24%) | catalogued as rs1009071087; called by muse, mutect2, varscan2
- EDDM13 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1306655740; called by muse, mutect2, varscan2
- EDEM3 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs748320398, COSV58923365; called by muse, mutect2, varscan2
- EDIL3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 57/382 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV56888905; called by muse, mutect2, varscan2
- EFCAB5 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.053); catalogued as rs763579493; called by muse, mutect2, varscan2
- EFCAB9 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs891172675; called by muse, mutect2, varscan2
- EFEMP1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 145/593 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62617821; called by muse, mutect2, varscan2
- EFNB2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 190/407 reads (47%) | catalogued as rs767489766; called by muse, mutect2, varscan2
- EGFLAM | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 106/471 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100380702; called by muse, mutect2, varscan2
- EGFLAM | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs868157572, COSV59292902, COSV59315167; called by muse, mutect2, varscan2
- EHD1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 96/429 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57737239; called by muse, mutect2, varscan2
- EIF3F | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 184/696 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs534364559; called by muse, mutect2, varscan2
- ELAPOR2 | c.2703G>A p.W901* (on ENST00000450689 / NM_001142749.3; = p.W734* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 106/310 reads (34%) | catalogued as COSV51889841; called by muse, mutect2, varscan2
- ELAVL2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99806680; called by muse, varscan2
- ELF3 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 151/431 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs772992282, COSV100668683, COSV100668877; called by muse, mutect2, varscan2
- ELF4 | c.1097T>C p.L366S | Missense Mutation (SNP) | VAF 177/685 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs867812609; called by muse, mutect2, varscan2
- ELFN2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 123/616 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV68744162; called by muse, mutect2, varscan2
- EMILIN2 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54426197; called by muse, mutect2, varscan2
- ENPEP | c.1575G>A p.E525= | Splice Region (SNP) | VAF 70/334 reads (21%) | catalogued as rs760065550; called by muse, mutect2, varscan2
- ENTPD2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 149/600 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756382655, COSV100445708; called by muse, mutect2, varscan2
- EOMES | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 131/523 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1351564397; called by muse, mutect2, varscan2
- EOMES | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 177/679 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.517); catalogued as rs749476578; called by muse, mutect2, varscan2
- EPB41 | c.1522C>T p.R508* (on ENST00000343067 / NM_001166005.2; = p.R299* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 100/414 reads (24%) | catalogued as COSV100548243; called by muse, mutect2, varscan2
- EPB41 | c.2170C>T p.P724S (on ENST00000343067 / NM_001166005.2; = p.P482S on NM_004437.4) | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV100548826, COSV100549615; called by muse, mutect2, varscan2
- EPHA1 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 277/764 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313505, COSV99313676; called by muse, mutect2, varscan2
- EPHA6 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV67566492; called by muse, mutect2, varscan2
- EPHA7 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65176855; called by muse, mutect2, varscan2
- EPHB1 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 118/559 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.045); catalogued as COSV67664944; called by muse, mutect2, varscan2
- EPHB2 | c.2134C>T p.R712W (on ENST00000400191 / NM_001309193.2; = p.R713W on NM_004442.7) | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375886598; called by muse, varscan2
- ERBB4 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 119/510 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53520038, COSV53578775; called by muse, mutect2, varscan2
- ERBB4 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV53504312; called by muse, mutect2, varscan2
- ERC2 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 91/383 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs184802404, COSV55660164; called by muse, mutect2, varscan2
- ERGIC1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 109/483 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV67128948; called by muse, mutect2, varscan2
- ERICH3 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs267598716, COSV58616091; called by muse, mutect2, varscan2
- ERICH3 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 141/586 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs751997045; called by muse, mutect2, varscan2
- ERICH3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1159893217, COSV58618484; called by muse, mutect2, varscan2
- ERICH3 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 89/440 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV100445538, COSV58615805; called by muse, mutect2, varscan2
- ERMP1 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99284743; called by muse, mutect2, varscan2
- ERN2 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 166/622 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs1215457559; called by muse, mutect2, varscan2
- ESS2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 131/519 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs758631784; called by muse, mutect2, varscan2
- ETAA1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55472278; called by muse, mutect2, varscan2
- ETFA | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.568); catalogued as rs775257101; called by muse, mutect2, varscan2
- EVC2 | c.3377C>T p.S1126L | Missense Mutation (SNP) | VAF 98/405 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs201735294; called by muse, mutect2, varscan2
- EVPL | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 114/713 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs747537304, COSV56907331; called by muse, mutect2, varscan2
- EVX2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 225/787 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100420833; called by muse, mutect2, varscan2
- EXOC4 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 241/622 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs760628284, COSV104390662; called by muse, mutect2, varscan2
- EXPH5 | c.3471G>A p.W1157* | Nonsense Mutation (SNP) | VAF 132/431 reads (31%) | catalogued as rs773991578; called by muse, mutect2, varscan2
- EYS | c.6725G>A p.R2242H | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65487656, COSV65512811, COSV65529301; called by muse, mutect2, varscan2
- EYS | c.5989G>A p.E1997K | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs1039263026, COSV65488122; called by muse, mutect2, varscan2
- EZR | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 141/554 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61453816; called by muse, mutect2, varscan2
- F11 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV53004426; called by muse, mutect2, varscan2
- F5 | c.4041C>A p.N1347K | Missense Mutation (SNP) | VAF 295/857 reads (34%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs747282664; called by muse, varscan2
- F5 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 123/740 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs991604301; called by muse, mutect2
- F8 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 146/591 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1557278509; called by muse, mutect2, varscan2
- F8 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.356); catalogued as CM0910944, CM920256, COSV64271718; called by muse, mutect2, varscan2
- F8 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 135/549 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.355); catalogued as CM011326; called by muse, mutect2, varscan2
- FAAH2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.065); catalogued as rs745882755, COSV100887429; called by muse, mutect2, varscan2
- FAAH2 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV66507405; called by muse, mutect2, varscan2
- FABP2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370366662; called by muse, mutect2, varscan2
- FAM135B | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 236/671 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV52708816; called by muse, mutect2, varscan2
- FAM135B | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV52718083; called by muse, mutect2, varscan2
- FAM135B | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 167/440 reads (38%) | catalogued as COSV50523324; called by muse, mutect2, varscan2
- FAM160A1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 118/600 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1217792211, COSV70706897; called by muse, mutect2, varscan2
- FAM161A | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 110/469 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs200458949; called by muse, mutect2, varscan2
- FAM163A | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 177/811 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336963076; called by muse, mutect2, varscan2
- FAM170A | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs1270846870, COSV100089291; called by muse, mutect2, varscan2
- FAM170A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 74/398 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58925617; called by muse, varscan2
- FAM170A | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 94/390 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV58926422; called by muse, mutect2, varscan2
- FAM171A1 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 124/586 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV65316358, COSV65316490; called by muse, mutect2, varscan2
- FAM184B | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 92/491 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs988071035; called by muse, mutect2, varscan2
- FAM193A | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 190/722 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs754694259; called by muse, mutect2, varscan2
- FAM20B | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 140/702 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as rs754757784; called by muse, mutect2, varscan2
- FAM20B | c.605A>T p.Y202F | Missense Mutation (SNP) | VAF 74/477 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs527462559; called by muse, mutect2, varscan2
- FAM214A | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs762303573; called by muse, mutect2, varscan2
- FAM3D | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 115/521 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62558768; called by muse, mutect2, varscan2
- FAM47A | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 127/645 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV60494142, COSV60495414; called by muse, mutect2, varscan2
- FAM47A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 124/619 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381450905, COSV60495984; called by muse, mutect2, varscan2
- FAM47B | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 148/680 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755619894, COSV61455915; called by muse, mutect2, varscan2
- FAM47C | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 166/739 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as rs782358582; called by muse, mutect2, varscan2
- FAM47C | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 149/688 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.208); catalogued as COSV63723912; called by muse, mutect2, varscan2
- FAM83C | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 278/785 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981758; called by muse, mutect2, varscan2
- FAM83H | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 187/714 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1206391189; called by muse, varscan2
- FANCI | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as rs770185523, COSV104407001; called by muse, mutect2, varscan2
- FAR1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1437945875, COSV61384625; called by muse, mutect2, varscan2
- FAT2 | c.9419C>T p.P3140L | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.392); catalogued as rs964169700, COSV55822673; called by muse, mutect2, varscan2
- FAT3 | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV53074534; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 83/358 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FAT4 | c.11765G>A p.G3922E | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1279158687, COSV58696470; called by muse, mutect2, varscan2
- FAT4 | c.13382G>A p.G4461E | Missense Mutation (SNP) | VAF 152/644 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58677892; called by muse, mutect2, varscan2
- FBF1 | c.1793G>A p.R598Q (on ENST00000586717; = p.R612Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 74/481 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as rs758649435; called by muse, varscan2
- FBH1 | c.961C>T p.L321F (on ENST00000362091 / NM_178150.3; = p.L372F on NM_032807.4) | Missense Mutation (SNP) | VAF 172/810 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62981818; called by muse, mutect2
- FBLN2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs1278624886, COSV99851587; called by muse, mutect2, varscan2
- FBLN5 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1319405796; called by muse, mutect2, varscan2
- FBN2 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.48); catalogued as COSV52509937; called by muse, mutect2, varscan2
- FBN3 | c.8236G>A p.E2746K | Missense Mutation (SNP) | VAF 191/725 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs780590806, COSV53664292; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FBN3 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs778407139; called by muse, mutect2, varscan2
- FBXL19 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 130/545 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs983034034, COSV57940884; called by muse, mutect2, varscan2
- FBXO15 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 112/692 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs761868127, COSV54043217, COSV54043698; called by muse, mutect2, varscan2
- FBXO15 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 191/471 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs144253482, COSV54044307; called by muse, mutect2, varscan2
- FBXO24 | c.1130G>A p.R377Q (on ENST00000241071 / NM_033506.3; = p.R415Q on NM_012172.5) | Missense Mutation (SNP) | VAF 207/563 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs752094310, COSV53828523; called by muse, mutect2, varscan2
- FBXO34 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 108/493 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1171559182; called by muse, mutect2, varscan2
- FBXO38 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57032164; called by muse, mutect2, varscan2
- FBXO4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV55853286; called by muse, mutect2, varscan2
- FBXO40 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1167347201, COSV57522777; called by muse, mutect2, varscan2
- FCRL3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765301809, COSV63845360; called by muse, varscan2
- FCRL5 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 179/508 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100709032; called by muse, mutect2, varscan2
- FCRL5 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 250/723 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as COSV62517425, COSV62517985; called by muse, mutect2, varscan2
- FER1L6 | c.3956G>A p.G1319E | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67549400; called by muse, mutect2, varscan2
- FFAR1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 119/440 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50070866; called by muse, mutect2, varscan2
- FGD3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 151/622 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs200081651; called by muse, mutect2, varscan2
- FGD5 | c.3923C>A p.P1308Q | Missense Mutation (SNP) | VAF 108/406 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV53247258; called by muse, mutect2, varscan2
- FGF21 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 135/554 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.46); catalogued as rs771805912; called by muse, mutect2, varscan2
- FGF7 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51065635; called by muse, mutect2, varscan2
- FGFR2 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as COSV60641683; called by muse, mutect2, varscan2
- FGFR3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 126/458 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs4647924, CM022207, CM960655, COSV53402284, COSV53409935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGG | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196319; called by muse, mutect2, varscan2
- FGG | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 80/343 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV60196542; called by muse, mutect2, varscan2
- FHAD1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538892644; called by muse, mutect2, varscan2
- FHIT | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 99/525 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100535947; called by muse, mutect2
- FILIP1 | c.2738G>A p.R913Q | Missense Mutation (SNP) | VAF 151/586 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1265762848, COSV52724695; called by muse, mutect2, varscan2
- FKBP5 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 111/600 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61881448; called by muse, mutect2, varscan2
- FLG | c.11705C>T p.P3902L | Missense Mutation (SNP) | VAF 201/519 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV64238219, COSV64238823; called by muse, mutect2, varscan2
- FLG | c.4870G>C p.E1624Q | Missense Mutation (SNP) | VAF 105/570 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as rs771190348; called by muse, mutect2, varscan2
6,508 further variants in this file (3,911 protein-altering or splice-affecting, 2,307 silent, 290 other) are not listed here.
